Gene-level copy-number profile of tumor specimen TCGA-CC-A3MC-01A from TCGA case TCGA-CC-A3MC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 54.9 years (20,067 days).
Specimen TCGA-CC-A3MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.44458e5e-f0e9-428c-b63a-7cf9f6492b41.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A3MC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e19fa2dc-fd3d-41b7-a164-730827901048

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,051; copy number 2: 44,563; copy number 3: 3,999; copy number 4: 3,397; copy number 6: 28; copy number 8: 781.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A3MC-01A-11D-A22E-01): tumor purity 0.64, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 809 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,548,562–171,251,857, 781 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr17:20,836,447–21,574,517, 28 genes, copy number 6 (within-gene range 1–6): CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5.

Autosomal genes at a single copy (total copy number 1): 4,664. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
